Somatic mutation profile of tumor specimen MMRF_2714_1_BM_CD138pos (aliquot MMRF_2714_1_BM_CD138pos_T1_KHS5U_L14830) from MMRF case MMRF_2714, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.9 years (22,962 days).
Specimen MMRF_2714_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a309db7-09a1-47be-a296-475550998ea7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2714_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2714_1_PB_WBC_C2_KHS5U_L14831; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/181f1f63-77a2-43c7-8f57-c06d1696ee5a

The open-access MAF lists 105 somatic variants for this specimen: 44 protein-altering or splice-affecting, 9 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, 3'UTR 31, Intron 10, Silent 9, 5'UTR 4, 3'Flank 3, Nonsense Mutation 3, 5'Flank 2, RNA 2, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAC1 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 10/31 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV61822410; called by muse, mutect2, varscan2
- CACNA2D1 | c.665C>G p.P222R | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.667); catalogued as COSV100667305; called by mutect2, varscan2
- DRC7 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); catalogued as rs376811117; called by muse, mutect2
- ENDOD1 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 45/118 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); catalogued as rs1555109605; called by muse, mutect2
- FAM222A | c.1190G>A p.C397Y | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62723358; called by muse, mutect2, varscan2
- GRIN2B | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as rs759714224, COSV101663269; called by muse, mutect2, varscan2
- GYS2 | c.538C>T p.H180Y | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs139544285, COSV53924211; called by muse, mutect2, varscan2
- HTR1F | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 13/359 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242288200; called by muse, mutect2
- IGHV2-70 | c.124A>G p.T42A | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.453); catalogued as rs373474286; called by muse, varscan2
- IGLV3-1 | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774205851; called by muse, varscan2
- IGLV3-1 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs61731683; called by muse, varscan2
- IGLV4-60 | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs372802349; called by muse, mutect2, varscan2
- KIF4B | c.2485C>T p.L829F | Missense Mutation (SNP) | VAF 115/223 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV70527574, COSV70528148; called by muse, mutect2, varscan2
- KMT2D | c.4384C>T p.L1462F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV56450246; called by muse, mutect2
- LTB | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 154/320 reads (48%) | catalogued as rs189982676, COSV59865148; called by muse, mutect2, varscan2
- MLH1 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 70/428 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs534184145; called by muse, mutect2, varscan2
- NCAM2 | c.2368G>T p.E790* | Nonsense Mutation (SNP) | VAF 39/262 reads (15%) | catalogued as COSV53083213; called by muse, mutect2, varscan2
- NPHP3 | c.2350G>C p.E784Q | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV100447047; called by muse, mutect2
- ODAPH | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1186139618; called by muse, mutect2
- RBBP8 | c.738del p.D247Ifs*7 | Frame Shift Del (DEL) | VAF 22/178 reads (12%) | catalogued as rs1304958368; called by mutect2, pindel, varscan2
- SPTBN2 | c.6766G>A p.G2256S | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.792); catalogued as rs112384228, COSV59447403; called by muse, mutect2, varscan2
- TBCD | c.3160G>T p.G1054C | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778040959, COSV62807599; called by muse, mutect2, varscan2
- TRIM9 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1362405363; called by muse, mutect2, varscan2
- ZNRF4 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs375118147; called by muse, mutect2, varscan2
- CD46 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- DLGAP5 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- DNM1L | c.1907T>G p.L636R (on ENST00000549701 / NM_012062.5; = p.L599R on NM_005690.4) | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEF1A1 | c.1210A>C p.M404L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HEPHL1 | c.3442C>T p.Q1148* | Nonsense Mutation (SNP) | VAF 38/271 reads (14%) | called by muse, mutect2, varscan2
- HNF1B | c.1270C>T p.H424Y | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HNRNPU | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IRX6 | c.999G>T p.E333D | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- KRT76 | c.1628G>A p.S543N | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LMTK3 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- MGAM | c.5039C>A p.A1680D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2
- MYO1E | c.1988A>C p.N663T | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- OR7G1 | c.670T>A p.S224T | Missense Mutation (SNP) | VAF 81/418 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PSMC5 | c.992T>C p.I331T | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- RAB11FIP1 | c.3253C>T p.P1085S | Missense Mutation (SNP) | VAF 68/186 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCARA5 | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SERPINA11 | c.499T>C p.S167P | Missense Mutation (SNP) | VAF 117/195 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TGM4 | c.1341G>C p.E447D | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2
- ZNF382 | c.1322G>A p.C441Y | Missense Mutation (SNP) | VAF 108/218 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF414 | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- BTBD16 | c.555C>A p.S185= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs767275051, COSV99584789; called by muse, mutect2, varscan2
- EIF4G2 | c.471G>A p.Q157= | Silent (SNP) | VAF 58/308 reads (19%) | called by muse, mutect2, varscan2
- FAM133A | c.240A>G p.L80= | Silent (SNP) | VAF 5/10 reads (50%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 87/122 reads (71%) | catalogued as rs367953381; called by muse, varscan2
- IGKV5-2 | c.15T>C p.V5= | Silent (SNP) | VAF 58/108 reads (54%) | called by muse, mutect2, varscan2
- MERTK | c.669G>A p.P223= | Silent (SNP) | VAF 32/120 reads (27%) | catalogued as rs750984679; called by muse, mutect2, varscan2
- OPCML | c.1023C>T p.F341= | Silent (SNP) | VAF 29/291 reads (10%) | called by muse, mutect2, varscan2
- PCDH7 | c.33C>T p.R11= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- TMC2 | c.972C>T p.Y324= | Silent (SNP) | VAF 23/105 reads (22%) | called by muse, mutect2, varscan2
- AP001042.1 | n.2665G>T | RNA (SNP) | VAF 18/85 reads (21%) | catalogued as rs1006367115; called by muse, mutect2, varscan2
- ARHGAP26 | c.*137T>G | 3'UTR (SNP) | VAF 45/159 reads (28%) | called by muse, mutect2, varscan2
- BEND4 | c.*5000C>T | 3'UTR (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- BHLHA15 | chr7:98212992 C>T | 3'Flank (SNP) | VAF 15/57 reads (26%) | catalogued as rs1490005545; called by muse, mutect2, varscan2
- BICD2 | c.*933T>C | 3'UTR (SNP) | VAF 43/87 reads (49%) | called by muse, mutect2, varscan2
- C10orf53 | c.217+152G>A | Intron (SNP) | VAF 22/82 reads (27%) | called by muse, mutect2, varscan2
- C11orf87 | c.*3938T>G | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- CARHSP1 | c.*2203T>G | 3'UTR (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- CATSPERG | c.-15+422_-15+423del | Intron (DEL) | VAF 39/119 reads (33%) | called by mutect2, pindel, varscan2
- CCL14 | c.*20G>A | 3'UTR (SNP) | VAF 46/146 reads (32%) | catalogued as rs745843281; called by muse, mutect2, varscan2
- CDK13 | c.-339C>T | 5'UTR (SNP) | VAF 49/205 reads (24%) | called by muse, mutect2, varscan2
- COL4A6 | c.*34C>T | 3'UTR (SNP) | VAF 23/33 reads (70%) | called by muse, mutect2, varscan2
- DUSP6 | c.-199C>T | 5'UTR (SNP) | VAF 4/70 reads (6%) | called by muse, mutect2
- EBF2 | c.*659G>T | 3'UTR (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- EPHA5 | c.*2493A>T | 3'UTR (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- EXPH5 | c.*1706G>A | 3'UTR (SNP) | VAF 19/50 reads (38%) | catalogued as rs770185554; called by muse, mutect2, varscan2
- FAM124A | c.*2251C>T | 3'UTR (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- FER | c.*5747G>A | 3'UTR (SNP) | VAF 54/114 reads (47%) | called by muse, mutect2, varscan2
- FOXF2 | c.*562T>C | 3'UTR (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- GPR85 | c.-484G>A | 5'UTR (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- GRIP2 | c.*4440A>T | 3'UTR (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- GULP1 | c.844-2386G>A | Intron (SNP) | VAF 18/71 reads (25%) | catalogued as rs764859688; called by muse, mutect2, varscan2
- IGHV1-69D | c.-28G>A | 5'UTR (SNP) | VAF 46/62 reads (74%) | called by muse, mutect2
- INTS9 | chr8:28890139 T>C | 5'Flank (SNP) | VAF 43/132 reads (33%) | called by muse, mutect2, varscan2
- KDM1A | c.*280_*281insGT | 3'UTR (INS) | VAF 6/46 reads (13%) | catalogued as rs1374737000; called by pindel, varscan2
- KMT5A | c.*405A>T | 3'UTR (SNP) | VAF 47/140 reads (34%) | called by muse, mutect2, varscan2
- MAPRE1 | c.*16G>A | 3'UTR (SNP) | VAF 179/425 reads (42%) | called by muse, mutect2, varscan2
- MCL1 | c.*2778_*2779del | 3'UTR (DEL) | VAF 8/70 reads (11%) | catalogued as rs754763165; called by mutect2, pindel, varscan2
- MMP28 | c.379+61G>A | Intron (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- MTA1 | c.1814-128_1814-125dup | Intron (INS) | VAF 14/24 reads (58%) | called by mutect2, varscan2
- MYB | c.1203+870C>T | Intron (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- PCSK9 | c.524-1028G>A | Intron (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- PELATON | n.229C>T | RNA (SNP) | VAF 19/58 reads (33%) | catalogued as rs748424775; called by muse, mutect2
- PHLDB2 | c.*318G>A | 3'UTR (SNP) | VAF 50/161 reads (31%) | catalogued as rs1474253286; called by muse, mutect2
- PPARGC1A | c.*967C>T | 3'UTR (SNP) | VAF 21/58 reads (36%) | catalogued as rs983358852; called by muse, mutect2, varscan2
- PRKCI | c.*2658T>G | 3'UTR (SNP) | VAF 102/294 reads (35%) | called by muse, mutect2, varscan2
- RAB20 | c.*35T>C | 3'UTR (SNP) | VAF 65/330 reads (20%) | called by muse, mutect2, varscan2
- RGMB | c.*936C>T | 3'UTR (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- RIDA | c.*398G>A | 3'UTR (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- SELENBP1 | c.5-187C>T | Intron (SNP) | VAF 48/154 reads (31%) | called by muse, mutect2, varscan2
- SF3B2 | c.*430C>T | 3'UTR (SNP) | VAF 6/167 reads (4%) | called by muse, mutect2
- SNORD116-17 | chr15:25087968 G>T | 3'Flank (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- SOCS6 | c.*2613T>A | 3'UTR (SNP) | VAF 7/160 reads (4%) | called by muse, mutect2
- TNKS | c.673+122T>G | Intron (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- TPRG1L | c.*160C>T | 3'UTR (SNP) | VAF 30/57 reads (53%) | catalogued as rs1378393105; called by muse, mutect2, varscan2
- TTPAL | c.*3783T>C | 3'UTR (SNP) | VAF 21/54 reads (39%) | catalogued as rs1018268608; called by muse, mutect2, varscan2
- TXNRD1 | c.305-1735G>A | Intron (SNP) | VAF 12/49 reads (24%) | catalogued as rs909184852; called by muse, mutect2, varscan2
- UNKL | chr16:1414724 G>T | 5'Flank (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- ZBTB18 | c.*1538A>G | 3'UTR (SNP) | VAF 28/68 reads (41%) | catalogued as COSV62396782; called by muse, varscan2
- ZBTB18 | c.*1647A>G | 3'UTR (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- ZBTB38 | chr3:141447638 G>A | 3'Flank (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- ZNF33A | c.*3225C>T | 3'UTR (SNP) | VAF 30/77 reads (39%) | catalogued as rs1130238; called by muse, mutect2, varscan2
